Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7477, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7477-01B (Primary Tumor).

Addendum Discussion:

The neoplastic cells are diffusely immunoreactive for p53, suggesting a astrocytic origin.
Numerous MIB-1 reactive cells are present with a labeling index estimated at 20%.
Although a minor population suggesting oligodendroglioma differentiation was seen, this strong
diffused p53 positivity argues against this and suggests that the apparent perinuclear halos were
simply cells with poor differentiation in a few processes.

Addendum Diagnosis:

Anaplastic Astrocytoma (WHO grade III)

Microscopic Description:

1, 2 sections demonstrate a markedly hypercellular glial neoplasm that diffusely infiltrates both gray and white matter. The majority of the tumor cells have an oligodendroglioma phenotype with perinuclear halos and fine branching vasculature. However, a significant minority of an astrocytoma phenotype is also seen. Atypica is moderate to focally marked. Numerous mitotic figures are seen. Neither microvascular proliferation nor necrosis are present.
3. Sections demonstrate a similar diffuse glial neoplasm. However, here most areas show a less cellular and infiltrating tumor.

ICD-0-3

astrocytoma, nos 9400/3

(CQCF) Site: supratentorial C71-0

hw
1/16/15

Source: NCI Genomic Data Commons file 50ebaf8c-c968-4d7c-b2ad-f3f9359c092e (TCGA-HT-7477.0BCE1BFA-C7D1-4A3E-A9DE-E24ABF6E5C4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).